Somatic mutation profile of tumor specimen HCM-STAN-0841-C18-01A (aliquot HCM-STAN-0841-C18-01A-11D-A882-36) from HCMI case HCM-STAN-0841-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G1; Age at diagnosis: 62.2 years (22,736 days).
Specimen HCM-STAN-0841-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3a44e61-15b5-45b3-9cbd-4c0fb50361b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0841-C18-11A (Solid Tissue Normal), aliquot HCM-STAN-0841-C18-11A-11D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b11d918b-f252-46af-981f-630d276a9830

The open-access MAF lists 128 somatic variants for this specimen: 86 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 38, Nonsense Mutation 5, Frame Shift Ins 3, Intron 3, Frame Shift Del 2, Splice Region 2, RNA 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC39 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 168/339 reads (50%) | catalogued as rs778577109; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 135/347 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.4018C>T p.R1340C | Missense Mutation (SNP) | VAF 190/257 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV52972567; called by muse, varscan2
- ADAM29 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs746641739, COSV63663321; called by muse, mutect2, varscan2
- AIM2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 130/357 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs149819770; called by muse, mutect2, varscan2
- ALK | c.2629G>T p.A877S | Missense Mutation (SNP) | VAF 124/303 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs746442213, COSV66594998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMOTL2 | c.1964G>A p.G655D | Missense Mutation (SNP) | VAF 221/452 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs1405117987; called by muse, mutect2, varscan2
- ARFGEF3 | c.5146G>A p.V1716M | Missense Mutation (SNP) | VAF 119/291 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52450815; called by muse, mutect2, varscan2
- ARHGEF40 | c.3778C>T p.R1260C | Missense Mutation (SNP) | VAF 182/249 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs573599814, COSV53879661; called by muse, mutect2, varscan2
- ATG2A | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 233/476 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs533644989, COSV65967112, COSV65967352; called by muse, mutect2, varscan2
- BCR | c.1461G>A p.A487= | Splice Region (SNP) | VAF 133/286 reads (47%) | catalogued as rs201526307, COSV100006358; called by muse, mutect2, varscan2
- CCDC185 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 197/474 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs867870627; called by muse, mutect2, varscan2
- CCDC92 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 179/678 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.768); catalogued as rs371993242; called by muse, mutect2, varscan2
- CERS3 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 226/283 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs563532463, COSV52569480; called by muse, mutect2, varscan2
- CROCC | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 146/234 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs750711172, COSV100978271; called by muse, varscan2
- CUL2 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs754713861, COSV66078712; called by muse, mutect2, varscan2
- CXXC5 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 254/562 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs113958458; called by muse, mutect2, varscan2
- DCLK1 | c.2101C>T p.R701C (on ENST00000360631 / NM_001330072.2; = p.D725= on NM_004734.5) | Missense Mutation (SNP) | VAF 94/728 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV55189268; called by muse, mutect2, varscan2
- ELOVL2 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 161/371 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as rs202019761, COSV61156962; called by muse, mutect2, varscan2
- FBLN2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 120/507 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs760367076; called by muse, mutect2, varscan2
- HOXC10 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 165/581 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs1343516622, COSV57726540; called by muse, mutect2, varscan2
- HYDIN | c.1449G>A p.A483= | Splice Region (SNP) | VAF 113/219 reads (52%) | catalogued as rs1224728357, COSV55490046; called by muse, mutect2, varscan2
- IRX2 | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 227/554 reads (41%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as COSV100121757; called by muse, mutect2, varscan2
- LIMS2 | c.50G>A p.R17H (on ENST00000355119 / NM_001161403.3; = p.R41H on NM_017980.4) | Missense Mutation (SNP) | VAF 197/470 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs775450533; called by muse, mutect2, varscan2
- LRRC4B | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 204/523 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV65349702; called by muse, mutect2, varscan2
- LRRTM3 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 156/340 reads (46%) | catalogued as COSV63661986; called by muse, mutect2
- MAP3K19 | c.1058del p.G353Vfs*24 | Frame Shift Del (DEL) | VAF 131/360 reads (36%) | catalogued as COSV59638811, COSV59640258; called by mutect2, pindel, varscan2
- METTL11B | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171914134; called by muse, mutect2, varscan2
- MORC1 | c.2641dup p.I881Nfs*11 | Frame Shift Ins (INS) | VAF 62/152 reads (41%) | catalogued as rs757379917; called by mutect2, varscan2
- MSN | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 218/562 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs766622413, COSV64303252; called by muse, mutect2, varscan2
- MYO1E | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 191/237 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178412708, COSV99896840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK5 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 86/712 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200564973; called by muse, mutect2, varscan2
- OR4C6 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 109/372 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs772626217, COSV58604155; called by muse, mutect2, varscan2
- PAPPA2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 142/376 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs1168232006, COSV62772967; called by muse, varscan2
- PCDHA8 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 260/602 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs145175505, COSV65323207, COSV65332790; called by muse, mutect2, varscan2
- PLXNA3 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 331/814 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs782778301; called by muse, mutect2, varscan2
- RBMS3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 116/233 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.701); catalogued as rs745458478, COSV56138386; called by muse, mutect2, varscan2
- RIN3 | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 176/224 reads (79%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.543); catalogued as rs1207521353, COSV104370381; called by muse, varscan2
- S1PR1 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 103/286 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs769569528, COSV59514504; called by muse, mutect2, varscan2
- SHROOM2 | c.3131G>A p.R1044Q | Missense Mutation (SNP) | VAF 387/849 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs776355945; called by muse, mutect2, varscan2
- SLC13A3 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 132/617 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs139768929; called by muse, mutect2, varscan2
- TKTL2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 189/360 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs905050983; called by muse, mutect2, varscan2
- TMEM185B | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 187/490 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1470518543; called by muse, varscan2
- TTC6 | c.3274C>T p.R1092* | Nonsense Mutation (SNP) | VAF 108/145 reads (74%) | catalogued as rs781407244; called by muse, mutect2, varscan2
- XRCC3 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 208/298 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780262052; called by muse, mutect2, varscan2
- ZFHX4 | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51487845; called by muse, mutect2, varscan2
- ZNF324B | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 174/526 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs919613361, COSV100351671; called by muse, mutect2, varscan2
- ABCB5 | c.2011-1G>T p.X671_splice (on ENST00000404938 / NM_001163941.2; = p.X226_splice on NM_178559.6) | Splice Site (SNP) | VAF 84/295 reads (28%) | called by muse, mutect2, varscan2
- AC068580.4 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 150/451 reads (33%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACAT2 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 185/456 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- AFF2 | c.3182C>A p.P1061H | Missense Mutation (SNP) | VAF 115/287 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APC | c.2820_2841delinsTTC p.E941Sfs*8 | Frame Shift Del (DEL) | VAF 94/282 reads (33%) | called by pindel, varscan2*
- APC | c.4166_4170delinsAGA p.S1389* | Nonsense Mutation (DEL) | VAF 147/395 reads (37%) | called by pindel, varscan2*
- CAPRIN2 | c.930C>G p.N310K | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CFAP47 | c.3175C>G p.P1059A | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP5 | c.2986A>G p.K996E | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DBF4 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 67/460 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DGKI | c.3083G>T p.G1028V | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DMD | c.2844G>A p.M948I | Missense Mutation (SNP) | VAF 182/422 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DMRTA1 | c.*3_*8dup | In Frame Ins (INS) | VAF 54/176 reads (31%) | called by mutect2, varscan2
- EEF1A1 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 103/358 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ENPP2 | c.1303T>C p.Y435H (on ENST00000075322 / NM_001040092.3; = p.Y487H on NM_006209.5) | Missense Mutation (SNP) | VAF 70/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM71D | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- GABPA | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- GSE1 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 91/711 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- HEATR5B | c.4798T>C p.C1600R | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HIVEP1 | c.455A>C p.D152A | Missense Mutation (SNP) | VAF 186/515 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- KLHL3 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 180/421 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KXD1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- LEMD3 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 181/393 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- LRTM2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 154/766 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, varscan2
- NUTM1 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 203/253 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PCDHAC1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 208/502 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB11 | c.507C>A p.S169R | Missense Mutation (SNP) | VAF 156/368 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCDHGA8 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 183/418 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLPPR4 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 139/331 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PRKCG | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.022); called by muse, varscan2
- RP1 | c.4465G>A p.A1489T | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPRD2 | c.1831A>G p.I611V | Missense Mutation (SNP) | VAF 195/514 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK2 | c.4689T>G p.Y1563* | Nonsense Mutation (SNP) | VAF 158/475 reads (33%) | called by muse, mutect2, varscan2
- SHISA7 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 146/798 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TENM4 | c.3167G>A p.G1056D | Missense Mutation (SNP) | VAF 80/305 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- TNC | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 88/402 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TNFRSF19 | c.1237T>G p.S413A | Missense Mutation (SNP) | VAF 375/518 reads (72%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TP53 | c.636dup p.R213Sfs*3 | Frame Shift Ins (INS) | VAF 176/315 reads (56%) | called by mutect2, pindel, varscan2
- VWA3A | c.923dup p.A309Cfs*11 | Frame Shift Ins (INS) | VAF 54/408 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTSL5 | c.156G>T p.G52= | Silent (SNP) | VAF 194/447 reads (43%) | called by muse, mutect2, varscan2
- BCL11B | c.1572G>A p.P524= (on ENST00000357195 / NM_001282237.2; = p.P453= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 312/434 reads (72%) | catalogued as rs758740380; called by muse, varscan2
- BHMT2 | c.864C>T p.G288= | Silent (SNP) | VAF 192/441 reads (44%) | catalogued as rs755500242, COSV54872597; called by muse, mutect2, varscan2
- COL13A1 | c.1506C>T p.R502= (on ENST00000398978 / NM_001130103.2; = p.R445= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/243 reads (25%) | catalogued as rs754892079, COSV62568712; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH3 | c.11727G>A p.S3909= | Silent (SNP) | VAF 96/639 reads (15%) | catalogued as rs758112425, COSV99767410; called by muse, mutect2, varscan2
- ERICH1 | c.804C>T p.D268= | Silent (SNP) | VAF 344/489 reads (70%) | catalogued as rs1387504904, COSV50640520; called by muse, mutect2, varscan2
- F13B | c.1368T>C p.V456= | Silent (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2
- FAM241B | c.42C>T p.D14= | Silent (SNP) | VAF 233/442 reads (53%) | catalogued as rs769897866, COSV64767984; called by muse, mutect2, varscan2
- FAM47B | c.915C>T p.S305= | Silent (SNP) | VAF 166/466 reads (36%) | catalogued as rs377737946, COSV61454438; called by muse, mutect2, varscan2
- FAM47C | c.2664G>A p.K888= | Silent (SNP) | VAF 251/652 reads (38%) | catalogued as COSV63725664; called by muse, mutect2, varscan2
- FLT4 | c.1491C>T p.A497= | Silent (SNP) | VAF 140/437 reads (32%) | catalogued as rs751517485, COSV56106016; called by muse, mutect2, varscan2
- GPR32 | c.1008G>A p.A336= | Silent (SNP) | VAF 192/416 reads (46%) | catalogued as rs761150764, COSV54515212; called by muse, mutect2, varscan2
- GRM4 | c.438G>A p.K146= | Silent (SNP) | VAF 221/553 reads (40%) | called by muse, mutect2, varscan2
- KCNA5 | c.273G>A p.P91= | Silent (SNP) | VAF 436/845 reads (52%) | called by muse, mutect2, varscan2
- MAP4 | c.3189C>T p.F1063= | Silent (SNP) | VAF 43/374 reads (11%) | catalogued as COSV53143695; called by muse, mutect2, varscan2
- MKRN3 | c.900G>A p.S300= | Silent (SNP) | VAF 276/354 reads (78%) | catalogued as COSV58810005; called by muse, mutect2, varscan2
- NALCN | c.5124C>T p.D1708= | Silent (SNP) | VAF 124/1482 reads (8%) | catalogued as rs1468254746, COSV51975679; called by muse, mutect2
- NALCN | c.1248C>T p.D416= | Silent (SNP) | VAF 495/610 reads (81%) | catalogued as rs767226604, COSV51928622; called by muse, mutect2, varscan2
- NIPSNAP3B | c.33G>T p.A11= | Silent (SNP) | VAF 74/457 reads (16%) | catalogued as rs142770381; called by muse, mutect2, varscan2
- NRXN1 | c.3846C>T p.A1282= | Silent (SNP) | VAF 222/509 reads (44%) | catalogued as rs1309946041, COSV60503131; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDE3A | c.2601T>C p.N867= | Silent (SNP) | VAF 183/367 reads (50%) | called by muse, mutect2, varscan2
- PNMA2 | c.1089C>T p.D363= | Silent (SNP) | VAF 14/199 reads (7%) | catalogued as rs202002019; called by muse, mutect2
- REXO1 | c.1143C>T p.T381= | Silent (SNP) | VAF 124/611 reads (20%) | catalogued as rs531507550; called by muse, mutect2, varscan2
- SCIN | c.825A>G p.A275= (on ENST00000297029 / NM_001112706.3; = p.A28= on NM_033128.3) | Silent (SNP) | VAF 181/601 reads (30%) | called by muse, mutect2, varscan2
- SCRT1 | c.333C>A p.G111= | Silent (SNP) | VAF 85/570 reads (15%) | called by muse, mutect2, varscan2
- SLC16A6 | c.633G>A p.P211= | Silent (SNP) | VAF 108/402 reads (27%) | catalogued as rs782764638; called by muse, mutect2
- SLC17A7 | c.1614G>A p.P538= | Silent (SNP) | VAF 45/314 reads (14%) | catalogued as rs546442351, COSV55546508; called by muse, varscan2
- SMC4 | c.1161A>G p.K387= | Silent (SNP) | VAF 75/143 reads (52%) | called by muse, mutect2, varscan2
- TECTA | c.3999C>T p.I1333= | Silent (SNP) | VAF 156/472 reads (33%) | catalogued as rs775746884, COSV99878734; called by muse, varscan2
- TMEM221 | c.669T>C p.C223= | Silent (SNP) | VAF 213/486 reads (44%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.2751G>A p.T917= | Silent (SNP) | VAF 51/149 reads (34%) | catalogued as rs771004816; called by muse, mutect2, varscan2
- TRAPPC11 | c.2034G>A p.V678= | Silent (SNP) | VAF 81/150 reads (54%) | catalogued as rs965136707; called by muse, mutect2, varscan2
- UBA6 | c.3057G>A p.K1019= | Silent (SNP) | VAF 55/228 reads (24%) | called by muse, mutect2, varscan2
- ZC3H15 | c.321C>T p.F107= | Silent (SNP) | VAF 124/302 reads (41%) | catalogued as rs1241385474; called by muse, mutect2, varscan2
- ZDBF2 | c.2133G>A p.P711= | Silent (SNP) | VAF 155/418 reads (37%) | catalogued as rs373918151; called by muse, mutect2, varscan2
- ZNF217 | c.2052A>G p.E684= | Silent (SNP) | VAF 404/641 reads (63%) | catalogued as rs767921932, COSV56594143; called by muse, mutect2, varscan2
- ZNF568 | c.387G>A p.A129= | Silent (SNP) | VAF 121/334 reads (36%) | catalogued as rs1354238378, COSV70893646; called by muse, varscan2
- ZNF750 | c.309G>A p.Q103= | Silent (SNP) | VAF 236/510 reads (46%) | called by muse, mutect2, varscan2
- C6orf136 | c.72+146A>G | Intron (SNP) | VAF 407/930 reads (44%) | catalogued as rs977537787; called by muse, mutect2, varscan2
- DCHS2 | n.5277G>A | RNA (SNP) | VAF 214/369 reads (58%) | catalogued as rs1318829771, COSV100601211; called by muse, mutect2, varscan2
- IRAK1 | c.136+36C>T | Intron (SNP) | VAF 77/574 reads (13%) | called by muse, mutect2, varscan2
- MAST1 | c.1366+59G>A | Intron (SNP) | VAF 178/466 reads (38%) | catalogued as rs779163962; called by muse, mutect2, varscan2
